CPTAC case C3N-01823 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3491e1f7-0c09-42f8-b20f-2a6d32426c64

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Dead; Days to death: 351 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 63.9 years (23,322 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 351 days; Progression or recurrence: yes; Days to last follow up: 351 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 8.3 cm); Lymph node involvement: Positive; Lymph nodes positive: 17; Lymph nodes tested: 21; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 351 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 181 days.

Other clinical attributes
- Weight: 75 kg; Height: 173 cm; BMI: 25.06; Comorbidities: Pancreatitis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-01823-01, C3N-01823-03 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 450 mg.
- Sample C3N-01823-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 420 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01823-22: Section location: Left Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3N-01823-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 210 mg; Time between clamping and freezing: 30 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-01823-31, C3N-01823-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01823-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
